Somatic mutation profile of tumor specimen TCGA-DD-AACY-01A (aliquot TCGA-DD-AACY-01A-11D-A40R-10) from TCGA case TCGA-DD-AACY, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 61.1 years (22,332 days).
Specimen TCGA-DD-AACY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f4e9d2b-faa9-4b82-abf2-9c10cc2e0955.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACY-10A (Blood Derived Normal), aliquot TCGA-DD-AACY-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06e089b8-d313-4eac-9b62-4ad05a740d75

The open-access MAF lists 91 somatic variants for this specimen: 70 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 20, Frame Shift Del 6, Splice Site 3, Splice Region 2, Frame Shift Ins 1, In Frame Ins 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2300_2308dup p.A767_V769dup | In Frame Ins (INS) | VAF 26/79 reads (33%) | hotspot (GDC flag); catalogued as rs727504263; ClinVar: drug response; called by mutect2, varscan2
- ACHE | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV99574001; called by muse, mutect2, varscan2
- AHNAK2 | c.14573G>T p.G4858V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.368); catalogued as COSV100317090; called by muse, mutect2, varscan2
- ANKRD11 | c.7747A>T p.N2583Y | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99969041; called by muse, mutect2, varscan2
- BNC2 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as COSV101032570, COSV101032941, COSV66152042; called by muse, mutect2, varscan2
- C1orf112 | c.2178A>C p.E726D | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99609660; called by muse, mutect2, varscan2
- C2CD3 | c.2055A>C p.E685D | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.72); catalogued as COSV100486513; called by muse, mutect2, varscan2
- CACUL1 | c.1004T>G p.L335R | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100432520; called by muse, mutect2, varscan2
- CARD14 | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100712540; called by muse, mutect2, varscan2
- CCT2 | c.1367A>G p.Y456C | Missense Mutation (SNP) | VAF 105/349 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100167589; called by muse, mutect2, varscan2
- CDC25C | c.260T>A p.L87H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV100086668; called by muse, mutect2, varscan2
- CELSR2 | c.7813A>T p.I2605F | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99603664; called by muse, mutect2, varscan2
- CENPB | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.515); catalogued as COSV100713387; called by muse, mutect2, varscan2
- COL1A1 | c.2980C>A p.R994S | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99867022; called by muse, mutect2, varscan2
- DHX32 | c.1561C>A p.H521N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99501579; called by muse, mutect2, varscan2
- DHX57 | c.3705T>G p.F1235L | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99769382; called by muse, mutect2, varscan2
- DNAH11 | c.10703T>A p.I3568N | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100178851; called by muse, mutect2, varscan2
- DNAI3 | c.64+1G>A p.X22_splice | Splice Site (SNP) | VAF 74/195 reads (38%) | catalogued as COSV99641697; called by muse, mutect2, varscan2
- EPAS1 | c.2452A>G p.K818E | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV99763122; called by muse, mutect2, varscan2
- EPHB1 | c.1412A>G p.Y471C | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV101213056, COSV67653752; called by muse, mutect2, varscan2
- FOXN2 | c.903T>G p.D301E | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100489144; called by muse, varscan2
- GPR22 | c.1250A>G p.E417G | Missense Mutation (SNP) | VAF 10/328 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV99771899; called by muse, mutect2
- HECW2 | c.3827C>G p.P1276R | Missense Mutation (SNP) | VAF 104/235 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99646826; called by muse, mutect2, varscan2
- HMOX1 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99330674; called by muse, mutect2, varscan2
- ITGA6 | c.1033A>G p.I345V (on ENST00000442250; = p.I306V on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs1256388995, COSV99905379; called by muse, mutect2, varscan2
- KIAA1109 | c.6757A>G p.I2253V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99155355; called by muse, mutect2, varscan2
- KMT2C | c.8527G>A p.D2843N | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV100070816; called by muse, mutect2, varscan2
- LRRIQ1 | c.660A>C p.K220N | Missense Mutation (SNP) | VAF 149/590 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV101277712; called by muse, mutect2, varscan2
- MAP3K7 | c.1475C>T p.S492L (on ENST00000369329 / NM_145331.3; = p.S465L on NM_003188.4) | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.549); catalogued as rs751903983, COSV100997481; called by muse, mutect2, varscan2
- MUC2 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.07); catalogued as rs781571861; called by muse, mutect2, varscan2
- MYO1F | c.3202A>G p.I1068V | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs1431657549, COSV100596623; called by muse, mutect2, varscan2
- NCOR1 | c.5550A>T p.E1850D | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV99249387; called by muse, mutect2, varscan2
- NMUR2 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs779692169, COSV54918661; called by muse, mutect2, varscan2
- NOP10 | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV60994986; called by muse, mutect2, varscan2
- PALMD | c.513A>G p.K171= | Splice Region (SNP) | VAF 98/290 reads (34%) | catalogued as rs751532207, COSV54163132; called by muse, mutect2, varscan2
- PDK1 | c.691+2T>G p.X231_splice | Splice Site (SNP) | VAF 26/77 reads (34%) | catalogued as COSV99961256; called by muse, mutect2, varscan2
- PLEKHS1 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs1463509140, COSV100613105, COSV63054217; called by muse, mutect2, varscan2
- PPARG | c.1208A>T p.N403I (on ENST00000287820 / NM_015869.5; = p.N373I on NM_005037.7) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99826417; called by muse, mutect2, varscan2
- PPP1R18 | c.1599A>T p.R533S | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99223661; called by muse, mutect2, varscan2
- PPP1R32 | c.468G>C p.Q156H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV100087782; called by muse, mutect2, varscan2
- PRRT1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs1449949512; called by muse, mutect2
- PRUNE2 | c.8894G>A p.G2965D | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99796019; called by muse, mutect2, varscan2
- PSMD8 | c.459A>T p.Q153H | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.081); catalogued as COSV99287431; called by muse, mutect2, varscan2
- RASA1 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 93/289 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV57201078, COSV99169749; called by muse, mutect2, varscan2
- RPL35A | c.41A>G p.Y14C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs1366033915, COSV99502258; called by muse, mutect2, varscan2
- RWDD3 | c.472A>G p.I158V | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99811557; called by muse, mutect2, varscan2
- SCMH1 | c.184A>T p.M62L (on ENST00000326197 / NM_001031694.2; = p.M15L on NM_012236.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100401610; called by muse, mutect2, varscan2
- SEMA5B | c.2525T>C p.L842P | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99531511; called by muse, mutect2
- SH3GL3 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100196500; called by muse, mutect2, varscan2
- SIRT4 | c.497+2T>G p.X166_splice | Splice Site (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99177413; called by muse, mutect2
- SMARCAL1 | c.2430G>T p.V810= | Splice Region (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100619862; called by muse, mutect2, varscan2
- SOCS3 | c.299del p.G100Afs*79 | Frame Shift Del (DEL) | VAF 35/114 reads (31%) | catalogued as rs1480367425; called by mutect2, pindel, varscan2
- SORBS1 | c.211G>T p.V71L (on ENST00000361941 / NM_001034954.2; = p.V39L on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1238773846, COSV99527857; called by muse, mutect2
- SPATA13 | c.1126C>G p.L376V | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100542150; called by muse, mutect2, varscan2
- SRGAP3 | c.677A>C p.Q226P | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV100840903; called by muse, mutect2, varscan2
- SUPT6H | c.4831C>T p.P1611S | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV99972642; called by muse, mutect2, varscan2
- TBC1D10A | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99304597; called by muse, mutect2, varscan2
- THOC2 | c.1823A>C p.N608T | Missense Mutation (SNP) | VAF 107/139 reads (77%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV99833145; called by muse, mutect2, varscan2
- TOR3A | c.821A>T p.N274I | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100751287; called by muse, mutect2, varscan2
- VIM | c.65G>T p.S22I | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV99813037; called by muse, mutect2, varscan2
- ZFHX3 | c.3341G>A p.R1114Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.127); catalogued as rs187631913, COSV51726666, COSV99195301; called by muse, mutect2, varscan2
- ZNF808 | c.828C>G p.C276W | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs753523035, COSV100707889; called by muse, mutect2
- ZNF83 | c.206A>C p.H69P | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV99991321; called by muse, mutect2, varscan2
- CABIN1 | c.4480_4506del p.P1494_E1502del | In Frame Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- FOXN2 | c.871_881del p.S291Qfs*3 | Frame Shift Del (DEL) | VAF 42/118 reads (36%) | called by pindel, varscan2
- MACF1 | c.12189dup p.V4064Sfs*4 (on ENST00000372915; = p.V1997Sfs*4 on NM_012090.5) | Frame Shift Ins (INS) | VAF 47/368 reads (13%) | called by mutect2, pindel, varscan2
- RFTN1 | c.1189del p.L397Wfs*63 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | called by mutect2, pindel, varscan2
- SAR1B | c.595del p.*199Nfs*26 | Frame Shift Del (DEL) | VAF 39/99 reads (39%) | called by mutect2, pindel, varscan2
- ZNF140 | c.411del p.R138Gfs*3 | Frame Shift Del (DEL) | VAF 54/178 reads (30%) | called by mutect2, varscan2
- ZNF503 | c.1228_1241del p.S410Rfs*25 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- CCDC102B | c.1416C>T p.L472= | Silent (SNP) | VAF 22/326 reads (7%) | catalogued as rs1251393331, COSV100103216; called by muse, mutect2
- CENPB | c.300C>G p.L100= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs767586180, COSV100713388, COSV60149087; called by muse, mutect2
- DHX32 | c.1560A>C p.S520= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV99501581; called by muse, mutect2, varscan2
- HAAO | c.12C>T p.R4= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV99685347; called by muse, mutect2, varscan2
- HSPB6 | c.177C>T p.S59= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs1005618052, COSV99137426; called by muse, mutect2
- KIF5C | c.2772G>A p.K924= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs1335876090, COSV101276124; called by muse, mutect2, varscan2
- KLF10 | c.918G>T p.V306= | Silent (SNP) | VAF 83/270 reads (31%) | catalogued as COSV99574718; called by muse, mutect2, varscan2
- MKKS | c.294T>G p.L98= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV100726271; called by muse, mutect2, varscan2
- NTRK3 | c.1266C>G p.T422= | Silent (SNP) | VAF 73/159 reads (46%) | catalogued as COSV100446327, COSV58106859; called by muse, mutect2, varscan2
- OR52N5 | c.294C>T p.L98= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as COSV100399667, COSV57698852; called by muse, mutect2
- OSBPL1A | c.1938C>A p.S646= (on ENST00000319481 / NM_080597.4; = p.S133= on NM_018030.4) | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV100111553; called by muse, mutect2, varscan2
- OSR1 | c.78A>C p.A26= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV99693649; called by muse, mutect2, varscan2
- PABPC1 | c.1104T>G p.A368= | Silent (SNP) | VAF 150/208 reads (72%) | catalogued as COSV100589496; called by muse, mutect2, varscan2
- PRKD2 | c.1302C>T p.T434= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV99354235; called by muse, mutect2, varscan2
- PXK | c.1590T>G p.P530= | Silent (SNP) | VAF 45/130 reads (35%) | catalogued as COSV100240132; called by muse, mutect2, varscan2
- RASA1 | c.975A>G p.T325= | Silent (SNP) | VAF 94/287 reads (33%) | catalogued as COSV99169748; called by muse, mutect2, varscan2
- TBC1D12 | c.1668A>T p.P556= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as COSV99831378; called by muse, mutect2, varscan2
- THNSL1 | c.102A>C p.S34= | Silent (SNP) | VAF 59/132 reads (45%) | catalogued as COSV100896175; called by muse, mutect2, varscan2
- TOB2 | c.84T>C p.F28= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100548390; called by muse, mutect2, varscan2
- TRRAP | c.9456G>T p.L3152= (on ENST00000359863 / NM_001244580.1; = p.L3123= on NM_003496.3) | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100722369; called by muse, mutect2, varscan2
- CARMIL3 | chr14:24048760 T>A | 5'Flank (SNP) | VAF 171/431 reads (40%) | called by muse, mutect2, varscan2
